Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0T4, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0T4-01A (Primary Tumor).

[page 1 of 3]
10A-0-3 Carcinoma, infiltrating lobular, NOS 852013
Site: breast, NOS C50.4 1/27/11 JH

Specimen: Received: Status: Req#:
Spec Type: SURGICAL P Subm Dr:

PREOPERATIVE DIAGNOSIS

RIGHT BREAST CANCER - IN SITU, LEFT FIBROCYSTIC BREAST CANCER

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: BILATERAL SIMPLE MASTECTOMY-SENTINEL NODE BX

TISSUE PROVIDED

- A. RT BREAST MASTECTOMY
- B. LT BREAST MASTECTOMY
- C. RT AXILLA SENTINEL NODE #1
- D. RT AXILLA NON SENTINEL NODE
- E. LT AXILLA SENTINEL NODE #1
- F. LT AXILLA SENTINEL NODE #2

GROSS DESCRIPTION

PART A RECEIVED FRESH LABELED [REDACTED] RIGHT BREAST INK MARKS TUMOR STITCH 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN WITH OVERALL DIMENSIONS OF 24.5 X 21 X 3.5 CM. THE NIPPLE IS UNREMARKABLE WITHIN A 6 X 3-CM ELLIPSE OF SKIN. A SUTURE DENOTES 12 O'CLOCK. ADJACENT TO THIS SUTURE IN THE UPPER INNER QUADRANT IS BLACK INK DENOTING THE TUMOR AREA. THIS AREA IS OVERMARKED WITH RED INK. THE SUPERFICIAL ASPECT OF THE SPECIMEN IS MARKED IN BLUE, THE DEEP IN BLACK INK. IN THE UPPER INNER QUADRANT, THERE IS A FIRM PALPABLE MASS MEASURING 2.3 X 3.3 X 1.7 CM. THIS IS 0.6 CM FROM THE DEEP MARGIN. A RIBBON CLIP IS IDENTIFIED WITHIN THIS MASS. A PORTION OF THIS IS SUBMITTED PER PROTOCOL. THE BREAST TISSUE CONSISTS OF A MIXTURE OF BLAND YELLOW FATTY TISSUE AND PINK-TAN FIBROUS TISSUE WHICH PRIMARILY IS CENTRAL AND COMPRISES NO MORE THAN 20% OF THE PARENCHYMA. THIS MASS IS 1.5 CM FROM THE SUPERFICIAL MARGIN. ADDITIONALLY WITHIN THE CONTAINER ARE TWO IRREGULAR PORTIONS OF YELLOW FATTY TISSUE MEASURING 8.5 X 8.3 X 1.5 CM TOGETHER. THIS TISSUE IS GROSSLY UNREMARKABLE AND NO SECTIONS ARE SUBMITTED. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE AND ADJACENT SKIN (MIRROR IMAGE TO PROTOCOL), A2--SUPERIOR PORTION OF LESION TO INCLUDE DEEP MARGIN (MIRROR IMAGE TO PROTOCOL), A3--THE REMAINDER OF THE FULL CROSS-SECTION TO A2 TO INCLUDE THE INFERIOR ASPECT OF THE LESION, A4--SECTION OF TISSUE IN AREA OF RIBBON CLIP (MIRROR IMAGE TO TUMOR BLOCK), A5--TISSUE TAKEN FROM UPPER OUTER QUADRANT 6 CM FROM THE LESION (MIRROR IMAGE TO PROTOCOL), A6--MEDIAL ASPECT OF LESION TO INCLUDE DEEP MARGIN, A7--TISSUE IMMEDIATELY LATERAL TO A6 NOT GROSSLY TUMOR, A8--REPRESENTATIVE LOWER OUTER QUADRANT, A9--REPRESENTATIVE LOWER INNER QUADRANT. A10--ADDITIONAL SECTION OF DEEP MARGIN. A11--TUMOR ADJACENT TO DEEP MARGIN WITHOUT INKED MARGIN PRESENT IN THE SECTION.

PART B RECEIVED FRESH LABELED [REDACTED] LEFT BREAST STITCH AT 12 O'CLOCK, IS A SIMPLE MASTECTOMY SPECIMEN MEASURING 22 X 18.5 X 3.3 CM.

[page 2 of 3]
(Continued)

Specimen: () Received: Status: Req#: Spec Type: SURGICAL P Subm Dr: (Continued)

THE NIPPLE IS UNREMARKABLE WITHIN A 6.3 X 3.9-CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. THE SUPERFICIAL ASPECT IS MARKED WITH BLUE INK, THE DEEP MARGIN WITH BLACK INK. SECTIONING REVEALS CENTRAL GRAY FIBROTIC TISSUE INTERMINGLED WITH YELLOW FATTY TISSUE WITH A PERIMETER OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. THE FIBROUS TISSUE COMPRISES 20% OF THE SPECIMEN. SECTIONS ARE SUBMITTED AS FOLLOWS: B1--NIPPLE, B2--UPPER INNER QUADRANT. (MIRROR IMAGE TO PROTOCOL), B3--UPPER INNER QUADRANT, B4 AND 5--LOWER INNER QUADRANT, B6 AND 7--LOWER OUTER QUADRANT, B8 AND 9--UPPER OUTER QUADRANT, B10--CENTRAL WITH DEEP MARGIN.

PART C RECEIVED FRESH LABELED [REDACTED] RIGHT AXILLA FIRST SENTINEL NODE HOT, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 3 X 2.2 X 1.2 CM. SECTIONING REVEALS A 1.2-CM GROSSLY FAT-REPLACED LYMPH NODE, SUBMITTED ENTIRELY LABELED C1. A SECOND 1-CM GROSSLY FAT-REPLACED LYMPH NODE IS IDENTIFIED. THIS IS SUBMITTED LABELED C2.

PART D RECEIVED FRESH LABELED [REDACTED] RIGHT AXILLA NONSENTINEL NODE, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 3 X 1.8 X 1.0 CM. SECTIONING REVEALS A 1.5-CM GROSSLY FAT-REPLACED LYMPH NODE, SUBMITTED LABELED D.

PART E RECEIVED FRESH LABELED [REDACTED] LEFT AXILLA FIRST SENTINEL NODE HOT, IS AN OVOID PORTION OF YELLOW FATTY TISSUE MEASURING 3.5 X 1.5 X 1.5 CM. SECTIONING REVEALS A 4-CM GROSSLY FAT-REPLACED LYMPH NODE, ENTIRELY SUBMITTED AS E1 AND 2.

PART F RECEIVED FRESH LABELED [REDACTED] LEFT AXILLA SECOND SENTINEL NODE, IS YELLOW FATTY TISSUE MEASURING 3.5 X 3.2 X 1.5 CM. EXAMINATION REVEALS A 1.2-CM IN GREATEST DIMENSION CENTRALLY FAT-REPLACED LYMPH NODE, SUBMITTED LABELED F. ONE ADDITIONAL 0.5-CM LYMPH NODE IS SUBMITTED ALSO LABELED F.

PATH PROCEDURES

PROCEDURES:

88305, 88307/5, IMMUNOPEROXIDAS/3, A BLK/11, B BLK/10, CBX X6/2, D BLK, EBX X6/2, FBX X6

FINAL DIAGNOSIS

PART A RIGHT SIMPLE MASTECTOMY: IN SITU AND INFILTRATING LOBULAR CARCINOMA. THE TUMOR IS NUCLEAR GRADE II/III WITH A LOW MITOTIC INDEX. THE TUMOR SPANS A MICROSCOPIC DISTANCE OF 3.3 CM IN THE UPPER INNER QUADRANT OF THE BREAST. THE TUMOR DOES HAVE A MICROSCOPIC MULTIFOCAL APPEARANCE WITHIN THIS QUADRANT, BUT SECTIONS OF BREAST TISSUE FROM OTHER QUADRANTS OF THE BREAST DO NOT SHOW EVIDENCE OF MALIGNANCY. THE DEEP MARGIN IS FREE OF TUMOR BY A DISTANCE OF 5 MM.

cat inlcis.
(R) ILC #1.2-3
(R) LCIS

(R) UIQ
3.3cm
Multifocal

[page 3 of 3]
(Continued)

Specimen:

Received:

Status:

Req#:

Spec Type: SURGICAL P

Subm Dr:

FINAL DIAGNOSIS

(Continued)

PART B LEFT SIMPLE MASTECTOMY: DIFFUSE PROLIFERATIVE FIBROCYSTIC CHANGES WITH AREAS OF ATYPICAL DUCT AND LOBULAR HYPERPLASIA AND EXTENSIVE MICROCALCIFICATION. NO EVIDENCE OF INVASIVE CARCINOMA.

PART C RIGHT AXILLARY SENTINEL LYMPH NODE #1, BIOPSY: LYMPH NODE WITH NO EVIDENCE OF METASTATIC DISEASE, SUPPORTED BY NEGATIVE CYTOKERATIN IMMUNOHISTOCHEMICAL STAINING.

PART D RIGHT AXILLARY NONSENTINEL LYMPH NODE, BIOPSY: LYMPH NODE WITH NO EVIDENCE OF METASTATIC DISEASE.

PARTS E AND F LEFT AXILLARY SENTINEL LYMPH NODES NUMBERS 1 AND 2, BIOPSIES: LYMPH NODES WITH NO EVIDENCE OF METASTATIC DISEASE, SUPPORTED BY NEGATIVE CYTOKERATIN IMMUNOHISTOCHEMISTRY.

CODE

1

Signed

(prelim.)

(signature on file)

Source: NCI Genomic Data Commons file a35a09a8-05b3-4077-b108-33c61caab5e3 (TCGA-A2-A0T4.5B685F7F-917D-41BA-A7AB-D0E15D457BC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).